Somatic mutation profile of tumor specimen TCGA-AJ-A3QS-01A (aliquot TCGA-AJ-A3QS-01A-11D-A228-09) from TCGA case TCGA-AJ-A3QS, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.9 years (21,162 days).
Specimen TCGA-AJ-A3QS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee0eb45b-1d68-420b-8719-6f18e72a499b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3QS-10A (Blood Derived Normal), aliquot TCGA-AJ-A3QS-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7bb02992-54a5-4789-91a8-fe9f148d1fc7

The open-access MAF lists 277 somatic variants for this specimen: 214 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 185, Silent 57, Nonsense Mutation 20, Frame Shift Del 5, RNA 3, Frame Shift Ins 2, Splice Site 2, 5'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3062A>G p.Y1021C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913288, CM126695, COSV55882161, COSV55997924; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TRPM1 | c.1900C>T p.R634* | Nonsense Mutation (SNP) | VAF 5/63 reads (8%) | catalogued as rs763546583, COSV99856201; ClinVar: pathogenic; called by muse, mutect2
- AARD | c.33G>C p.E11D | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100991919; called by muse, mutect2
- ABCA12 | c.1175C>T p.S392L (on ENST00000272895 / NM_173076.3; = p.S74L on NM_015657.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs768608429, COSV99790782; called by muse, mutect2, varscan2
- ABCF2 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs775101547, COSV55185200; called by muse, mutect2, varscan2
- ADA2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV99376220; called by muse, mutect2, varscan2
- ADGRV1 | c.12672G>C p.L4224F | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV101315988, COSV101316164; called by muse, mutect2, varscan2
- AKAP3 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs201978763, COSV99962335; called by muse, mutect2, varscan2
- AMOTL2 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99998236; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.1048C>A p.H350N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99783780; called by muse, mutect2
- APMAP | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99468814; called by muse, mutect2, varscan2
- APOBEC3B | c.190C>T p.Q64* | Nonsense Mutation (SNP) | VAF 23/205 reads (11%) | catalogued as COSV100213811, COSV104410235; called by muse, mutect2, varscan2
- AR | c.84G>C p.Q28H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as COSV65955250; called by muse, mutect2, varscan2
- ARAF | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99283325; called by muse, mutect2
- ARFGEF2 | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.028); catalogued as COSV100904348; called by muse, mutect2, varscan2
- ARHGAP15 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as COSV99711893; called by muse, mutect2, varscan2
- ARL4A | c.414G>C p.L138F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1050948829, COSV100775938; called by muse, mutect2
- ATP2A1 | c.2865G>A p.M955I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV62869061; called by muse, mutect2, varscan2
- AXL | c.1381G>T p.A461S (on ENST00000301178 / NM_021913.5; = p.A452S on NM_001699.6) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.643); catalogued as rs781747516, COSV99996810; called by muse, mutect2, varscan2
- BCAT2 | c.1119G>C p.Q373H | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100302490, COSV100302512; called by muse, mutect2
- BEGAIN | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | catalogued as COSV100766993, COSV62068543; called by muse, mutect2, varscan2
- C14orf28 | c.242C>G p.S81C | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV100290284; called by muse, mutect2, varscan2
- CACNA1C | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100219966; called by muse, mutect2, varscan2
- CALD1 | c.1959G>C p.L653F (on ENST00000361675 / NM_033138.4; = p.L398F on NM_004342.7) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100724377; called by muse, mutect2, varscan2
- CAPN1 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV99658763; called by muse, mutect2, varscan2
- CASP3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776881401, COSV100395013; called by muse, mutect2, varscan2
- CBLC | c.1026G>A p.W342* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV99542171; called by muse, mutect2, varscan2
- CCSER1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100393771, COSV61451381; called by muse, mutect2, varscan2
- CDC6 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV52931544, COSV99266628; called by muse, mutect2
- CDH23 | c.8785G>A p.V2929M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs781604742, COSV56473634; called by muse, mutect2, varscan2
- CENPE | c.3118G>T p.E1040* | Nonsense Mutation (SNP) | VAF 31/200 reads (16%) | catalogued as COSV54388739, COSV99478434; called by muse, mutect2, varscan2
- CFAP52 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1201094620, COSV100235359; called by muse, mutect2, varscan2
- CHMP7 | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.087); catalogued as rs139229850, COSV100500648; called by muse, mutect2, varscan2
- CHUK | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV64918054; called by muse, mutect2, varscan2
- CLK2 | c.928G>C p.E310Q (on ENST00000368361 / NM_001294339.2; = p.E309Q on NM_003993.4) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as COSV100226807, COSV56945955; called by muse, mutect2, varscan2
- CLMN | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | catalogued as COSV100112440, COSV54187367; called by muse, mutect2, varscan2
- COL2A1 | c.3203G>T p.G1068V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100476894; called by muse, mutect2, varscan2
- COL5A1 | c.4705C>T p.P1569S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs1314380963, COSV100880146; called by mutect2, varscan2
- CPNE3 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV99547817; called by muse, mutect2, varscan2
- CPXM1 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101013781; called by muse, mutect2, varscan2
- CRYBG2 | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1470636343, COSV57485039; called by muse, mutect2, varscan2
- DAG1 | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV100445031; called by muse, mutect2
- DIP2A | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100595649, COSV100596071; called by muse, mutect2, varscan2
- DISP1 | c.3079C>G p.L1027V | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99451426, COSV99451638; called by muse, mutect2, varscan2
- DMBT1 | c.5060C>T p.A1687V (on ENST00000338354 / NM_001377530.1; = p.A930V on NM_004406.3) | Missense Mutation (SNP) | VAF 90/518 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs540411429, COSV100353451; called by muse, mutect2, varscan2
- DNAAF2 | c.1903C>G p.L635V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100024177; called by muse, mutect2, varscan2
- DNAJC28 | c.870G>C p.K290N | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100074739; called by muse, mutect2, varscan2
- DNTTIP2 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63284441; called by muse, mutect2, varscan2
- DPP6 | c.511G>A p.E171K (on ENST00000377770 / NM_001364500.2; = p.E109K on NM_001936.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.46); catalogued as rs1461095353, COSV59596064; called by muse, mutect2, varscan2
- DSEL | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100025835; called by muse, mutect2, varscan2
- DST | c.13660C>T p.Q4554* (on ENST00000361203 / NM_001374722.1; = p.Q2142* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as COSV99757902; called by muse, mutect2, varscan2
- DTL | c.1942G>C p.E648Q | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV100877235; called by muse, mutect2
- DYNC2I2 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV100823758, COSV63987085; called by muse, mutect2, varscan2
- DYSF | c.5170C>T p.Q1724* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as rs745680174, COSV99248541; called by muse, mutect2, varscan2
- EIF2AK4 | c.2980G>C p.E994Q | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99774962; called by muse, mutect2, varscan2
- EIF4G3 | c.147G>C p.M49I | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV99944846; called by muse, mutect2
- EOMES | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1045041330, COSV55411844, COSV55412183; called by muse, mutect2, varscan2
- EP300 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760816512, COSV99609108; called by muse, mutect2, varscan2
- EPHA5 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.217); catalogued as COSV56647082, COSV99899897; called by muse, mutect2, varscan2
- EPX | c.347-1G>C p.X116_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99836624; called by muse, mutect2, varscan2
- ERC2 | c.2314C>G p.Q772E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs772165287, COSV55674984, COSV99880102; called by muse, mutect2, varscan2
- ESX1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101006480; called by muse, mutect2, varscan2
- EXOC6 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 35/152 reads (23%) | catalogued as COSV99592162; called by muse, mutect2, varscan2
- FANCM | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV57505425, COSV57507675; called by muse, mutect2, varscan2
- FAT1 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV71671761, COSV71675565; called by muse, mutect2, varscan2
- FBXO11 | c.2678G>A p.G893E (on ENST00000403359 / NM_001190274.2; = p.G809E on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99316376; called by muse, mutect2, varscan2
- FSD1 | c.582G>C p.K194N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.875); catalogued as COSV99696877; called by muse, mutect2, varscan2
- GLG1 | c.856C>G p.Q286E | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1473741646, COSV52670597, COSV99216022; called by muse, mutect2, varscan2
- GPA33 | c.213C>G p.I71M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV100901139; called by mutect2, varscan2
- GPC2 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs369401121; called by muse, mutect2, varscan2
- GPR158 | c.3502C>T p.R1168* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as rs755737179, COSV100893899; called by muse, mutect2, varscan2
- GPRIN3 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.037); catalogued as COSV100310834, COSV60884180; called by muse, mutect2, varscan2
- GSN | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100376391; called by muse, mutect2, varscan2
- GTSF1 | c.362G>C p.W121S | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100007512; called by muse, mutect2, varscan2
- HCK | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99394236; called by muse, mutect2, varscan2
- HDAC2 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.811); catalogued as COSV64038135, COSV64038199; called by muse, mutect2, varscan2
- HECTD4 | c.11188G>A p.E3730K | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.364); catalogued as COSV101107939, COSV66389896; called by muse, mutect2, varscan2
- HECW2 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.012); catalogued as COSV99647798; called by muse, mutect2, varscan2
- HERPUD1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100296005; called by muse, mutect2, varscan2
- HMX2 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100378800; called by muse, mutect2
- IAH1 | c.645G>T p.L215F | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV100176367; called by muse, mutect2
- IFT122 | c.1933G>C p.D645H (on ENST00000348417 / NM_052989.3; = p.D586H on NM_018262.4) | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99959530; called by muse, mutect2, varscan2
- INPP5D | c.1626G>C p.L542F (on ENST00000445964 / NM_001017915.3; = p.L541F on NM_005541.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100856855; called by muse, mutect2, varscan2
- KASH5 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.024); catalogued as COSV101483469; called by muse, mutect2, varscan2
- KCNB1 | c.2548C>A p.H850N | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.075); catalogued as COSV100870533; called by muse, mutect2, varscan2
- KCNC3 | c.2070G>C p.K690N | Missense Mutation (SNP) | VAF 69/386 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.113); catalogued as rs964808763, COSV100979302; called by muse, mutect2, varscan2
- KDM4D | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1439665514, COSV100624295; called by muse, mutect2, varscan2
- KIF13B | c.2433C>G p.F811L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV101568711; called by muse, varscan2
- KRT37 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 131/180 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs779867248, COSV56658396; called by muse, mutect2, varscan2
- KRT80 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.098); catalogued as COSV100502730; called by muse, mutect2, varscan2
- KXD1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.246); catalogued as COSV99723696; called by muse, mutect2
- LCE1C | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100908459; called by muse, mutect2, varscan2
- LRIF1 | c.260C>G p.S87C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100870876; called by muse, mutect2, varscan2
- LRP1B | c.4159C>G p.P1387A | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101257751, COSV101257991; called by muse, mutect2, varscan2
- LUC7L3 | c.1231G>C p.D411H | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.615); catalogued as COSV53589095, COSV99537010; called by muse, mutect2, varscan2
- LVRN | c.1768C>G p.Q590E | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as COSV100773561; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1964A>C p.K655T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV99571577; called by muse, mutect2, varscan2
- MED14 | c.4266T>G p.F1422L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV100247540; called by muse, varscan2
- MEFV | c.2071G>A p.V691M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99561061; called by muse, mutect2, varscan2
- MIA3 | c.2050G>C p.E684Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100719488; called by muse, mutect2, varscan2
- MIIP | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99337674; called by muse, mutect2, varscan2
- MMP9 | c.2019C>A p.F673L | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748636725, COSV100812429; called by muse, mutect2, varscan2
- MRPL32 | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.051); catalogued as COSV56237718; called by muse, mutect2, varscan2
- MUC16 | c.18670C>T p.Q6224* | Nonsense Mutation (SNP) | VAF 38/353 reads (11%) | catalogued as COSV101200371; called by muse, mutect2
- MUC16 | c.14342C>G p.S4781C | Missense Mutation (SNP) | VAF 30/247 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV101200372, COSV99064275; called by muse, mutect2, varscan2
- MUC16 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.701); catalogued as COSV101200375; called by muse, mutect2
- NAV1 | c.4733G>A p.R1578H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs781210039, COSV99819145; called by muse, mutect2, varscan2
- NFE2L2 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.123); catalogued as COSV67962175; called by muse, mutect2, varscan2
- NOP14 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV100054819; called by muse, mutect2, varscan2
- NRP1 | c.1730G>C p.R577T | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99589116; called by muse, mutect2, varscan2
- NVL | c.609G>C p.E203D | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV55875596, COSV99894653; called by muse, mutect2, varscan2
- OR2Z1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.838); catalogued as COSV60693635; called by muse, mutect2
- OR4D5 | c.662T>G p.L221R | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100190055; called by muse, mutect2, varscan2
- PARD6A | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749999364, COSV54669056; called by muse, mutect2, varscan2
- PCDH10 | c.926G>C p.R309T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1167200103, COSV99993961; called by mutect2, varscan2
- PCDHB7 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.334); catalogued as COSV50762150, COSV50823479; called by muse, mutect2, varscan2
- PCLO | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100426308; called by muse, mutect2, varscan2
- PDP1 | c.1098G>C p.K366N | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV52603625; called by muse, mutect2, varscan2
- PEAK1 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV100433207; called by muse, mutect2, varscan2
- PELI2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.146); catalogued as rs557894615, COSV50710236; called by muse, mutect2, varscan2
- PLCE1 | c.5562G>C p.Q1854H | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV99595731; called by muse, mutect2, varscan2
- PLEKHG2 | c.2503G>C p.E835Q | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99216732, COSV99217741; called by muse, mutect2
- PLEKHG4 | c.2979G>C p.E993D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100431065; called by muse, mutect2, varscan2
- PLXNB2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.498); catalogued as COSV100834150; called by muse, mutect2, varscan2
- POTEE | c.3143C>T p.S1048L | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as rs1194969990, COSV100388352; called by muse, mutect2, varscan2
- POU1F1 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100622711; called by muse, mutect2, varscan2
- PPP1R3A | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99493380; called by muse, mutect2, varscan2
- PPP2CA | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.237); catalogued as COSV99196044; called by muse, mutect2, varscan2
- PRAM1 | c.1290G>T p.R430S | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99725684; called by muse, mutect2
- PRKCSH | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.455); catalogued as rs3211439, COSV99371721; called by muse, mutect2, varscan2
- PRUNE2 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100943119; called by muse, mutect2, varscan2
- PSG3 | c.1037C>G p.S346* | Nonsense Mutation (SNP) | VAF 50/312 reads (16%) | catalogued as rs1223764226, COSV100549105; called by muse, mutect2, varscan2
- PSMA8 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100378970; called by muse, mutect2, varscan2
- PSRC1 | c.741C>G p.I247M (on ENST00000409138 / NM_001363309.1; = p.I217M on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV100883526; called by muse, mutect2, varscan2
- PTPN13 | c.4108G>A p.E1370K (on ENST00000411767 / NM_080683.3; = p.E1351K on NM_006264.3) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV100365061; called by muse, mutect2, varscan2
- RB1CC1 | c.3718G>T p.E1240* | Nonsense Mutation (SNP) | VAF 16/122 reads (13%) | catalogued as COSV50246694, COSV99212439; called by muse, mutect2, varscan2
- RBM25 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99998852; called by muse, mutect2, varscan2
- RBP3 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs782074671; called by muse, mutect2, varscan2
- RC3H1 | c.2926C>G p.Q976E | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV99281518; called by muse, mutect2, varscan2
- REST | c.3209G>C p.R1070T | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100471058, COSV100471148; called by muse, mutect2, varscan2
- REXO5 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as rs745451778, COSV99759308; called by muse, mutect2, varscan2
- RIMS3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV101013477; called by muse, mutect2, varscan2
- RNF126 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV99443252; called by muse, mutect2, varscan2
- RNF148 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100411660; called by muse, mutect2, varscan2
- RSPH10B | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 40/314 reads (13%) | catalogued as COSV100382878, COSV58073751; called by muse, mutect2, varscan2
- RYR1 | c.4372C>G p.Q1458E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.928); catalogued as COSV100616215; called by muse, mutect2
- SAP130 | c.1018G>C p.D340H | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99384959; called by muse, mutect2, varscan2
- SCFD2 | c.1759G>C p.E587Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV101189308, COSV101189422; called by muse, mutect2, varscan2
- SCN10A | c.4891C>G p.H1631D | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV101479450, COSV71860438; called by muse, mutect2, varscan2
- SETD5 | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100200844; called by muse, mutect2, varscan2
- SF1 | c.356T>G p.L119R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV99918516; called by muse, mutect2, varscan2
- SLC43A3 | c.204G>C p.E68D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV100725227; called by muse, mutect2, varscan2
- SMCO1 | c.45G>C p.M15I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV101285021, COSV66877411; called by muse, mutect2
- SMG5 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100700843; called by muse, mutect2, varscan2
- SNTB2 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100293243; called by mutect2, varscan2
- SP4 | c.1339C>A p.Q447K | Missense Mutation (SNP) | VAF 15/224 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.191); catalogued as COSV99754713; called by muse, mutect2
- SPG7 | c.1956C>A p.Y652* (on ENST00000268704; = p.Y659* on NM_003119.4) | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV99245109; called by muse, mutect2
- SPNS1 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV100209136; called by muse, mutect2, varscan2
- SREK1 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as rs200372797; called by muse, mutect2, varscan2
- SUCNR1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100751780; called by muse, mutect2, varscan2
- SYNE1 | c.4027G>A p.E1343K (on ENST00000367255 / NM_182961.4; = p.E1350K on NM_033071.3) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV99570598; called by muse, mutect2, varscan2
- TBC1D13 | c.945C>A p.F315L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV99804299, COSV99804559; called by muse, mutect2, varscan2
- TBC1D22B | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.03); catalogued as COSV100996851; called by muse, mutect2, varscan2
- TBC1D28 | c.360C>G p.I120M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.521); catalogued as COSV100561039; called by muse, mutect2, varscan2
- TBC1D5 | c.1879G>C p.E627Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.975); catalogued as COSV99511167; called by muse, mutect2, varscan2
- TCERG1 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.932); catalogued as COSV99695037; called by muse, mutect2, varscan2
- TEPSIN | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 95/159 reads (60%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.54); catalogued as rs201854708, COSV100329775; called by muse, mutect2, varscan2
- TMC6 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 83/123 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1052987266, COSV100130218; called by muse, mutect2, varscan2
- TMCC1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100261161, COSV104412586; called by muse, varscan2
- TNFAIP6 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV104388527, COSV99693970; called by muse, mutect2, varscan2
- TNFSF8 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768032202, COSV99801936; called by muse, varscan2
- TNPO3 | c.1792C>G p.Q598E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99603152; called by muse, mutect2, varscan2
- TP53 | c.468del p.V157Sfs*13 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as COSV52675486, COSV53198467, COSV53663860; called by mutect2, pindel, varscan2
- TRAP1 | c.894C>G p.I298M | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99893665; called by muse, mutect2, varscan2
- TTN | c.65997G>T p.Q21999H (on ENST00000591111; = p.Q14575H on NM_003319.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | PolyPhen possibly damaging (0.847); catalogued as COSV100619844; called by muse, mutect2, varscan2
- TTN | c.31279G>A p.E10427K (on ENST00000591111; = p.E9500K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | PolyPhen benign (0.115); catalogued as COSV100619845; called by muse, mutect2, varscan2
- TTN | c.16156G>A p.D5386N (on ENST00000591111; = p.D4459N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | PolyPhen probably damaging (0.998); catalogued as COSV100619846; called by muse, mutect2, varscan2
- TUBA8 | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.297); catalogued as COSV100283161; called by muse, mutect2, varscan2
- TUBGCP6 | c.4163C>G p.S1388* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99955880; called by muse, mutect2, varscan2
- TYRP1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as rs754974316, COSV101141375, COSV66357698; called by muse, mutect2, varscan2
- UBA7 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201519366, COSV100339800; called by muse, mutect2, varscan2
- UBE4B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99477106; called by muse, mutect2, varscan2
- UPF2 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100707341; called by muse, mutect2, varscan2
- UQCRC1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs11539918, COSV99178995; called by muse, mutect2, varscan2
- USP16 | c.1545G>C p.L515F | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as rs1312086914, COSV100537994; called by muse, mutect2, varscan2
- USP33 | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100657158; called by muse, mutect2, varscan2
- USP42 | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV100084677; called by muse, mutect2, varscan2
- VCPIP1 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100125697; called by muse, mutect2, varscan2
- WASHC5 | c.333-1G>C p.X111_splice | Splice Site (SNP) | VAF 11/132 reads (8%) | catalogued as COSV100572927; called by muse, mutect2
- WDR47 | c.1600G>C p.D534H (on ENST00000369962 / NM_001142551.2; = p.D535H on NM_014969.5) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV100728383, COSV63057432; called by muse, mutect2, varscan2
- XRN1 | c.1729G>T p.A577S | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99378363; called by muse, mutect2
- YAP1 | c.825G>C p.Q275H (on ENST00000282441 / NM_001130145.3; = p.Q237H on NM_006106.5) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); catalogued as COSV99176211; called by muse, mutect2, varscan2
- ZFYVE19 | c.528G>A p.M176I (on ENST00000355341 / NM_001077268.2; = p.M166I on NM_032850.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99591754; called by muse, mutect2, varscan2
- ZMYM6 | c.490G>C p.D164H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.525); catalogued as COSV100451641; called by muse, mutect2, varscan2
- ZNF197 | c.2660G>C p.R887T | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.25); catalogued as COSV56077277; called by muse, mutect2, varscan2
- ZNF208 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV68102116; called by muse, mutect2
- ZNF219 | c.557A>G p.H186R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV100070479; called by muse, mutect2, varscan2
- ZNF394 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100460263; called by muse, mutect2, varscan2
- ZNF426 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV99465266; called by muse, mutect2
- ZSCAN10 | c.2164G>A p.E722K (on ENST00000252463; = p.E777K on NM_032805.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs910483646, COSV99374165; called by muse, mutect2, varscan2
- ANGEL1 | c.1218G>C p.Q406H | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CIITA | c.486del p.E162Dfs*6 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, varscan2
- CIITA | c.492del p.T165Lfs*3 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2*, pindel, varscan2*
- CNKSR2 | c.2635G>A p.E879K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GDF2 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- OR8G2P | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- PDE12 | c.1117dup p.V373Gfs*18 | Frame Shift Ins (INS) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.3967G>C p.E1323Q (on ENST00000414982 / NM_001166111.2; = p.E1275Q on NM_006702.5) | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- ROGDI | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.154); called by muse, mutect2
- TRIP12 | c.178dup p.T60Nfs*6 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | called by mutect2, pindel
- TRNT1 | c.4del p.L2* | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- ZSWIM4 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZSWIM4 | c.2365_2387del p.Y789Gfs*252 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- ABCC10 | c.1845G>A p.E615= (on ENST00000372530 / NM_001198934.2; = p.E587= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV99767548; called by muse, mutect2, varscan2
- ADCY3 | c.1956C>G p.L652= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs751217943, COSV99568614; called by muse, mutect2
- ALDH2 | c.1014G>C p.R338= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99923091; called by muse, mutect2, varscan2
- ARHGAP36 | c.1020C>T p.H340= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV99357879; called by mutect2, varscan2
- ARHGEF18 | c.639G>T p.L213= (on ENST00000359920 / NM_001130955.2; = p.L109= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV60475357; called by muse, mutect2
- CELSR1 | c.864C>T p.F288= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs146081380; called by muse, mutect2, varscan2
- CLVS2 | c.300G>A p.L100= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99253147; called by muse, mutect2
- CNNM2 | c.825C>T p.L275= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs766543892, COSV100881736; called by muse, varscan2
- DLEC1 | c.4467C>G p.P1489= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100342821, COSV100343790, COSV57300288; called by muse, mutect2, varscan2
- DMGDH | c.498T>C p.P166= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV99669210; called by muse, mutect2, varscan2
- EMP3 | c.491G>A p.*164= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99507379; called by muse, mutect2, varscan2
- EPB41L5 | c.126C>T p.I42= | Silent (SNP) | VAF 47/141 reads (33%) | catalogued as rs367826894; called by muse, mutect2, varscan2
- GRIK5 | c.1677C>T p.C559= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs372250624; called by muse, mutect2, varscan2
- GYS1 | c.582G>A p.R194= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99620906; called by muse, mutect2, varscan2
- HVCN1 | c.651C>T p.I217= | Silent (SNP) | VAF 25/89 reads (28%) | catalogued as COSV54371113; called by muse, mutect2, varscan2
- IQGAP1 | c.1782C>T p.I594= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV51591566; called by muse, mutect2, varscan2
- KIF13B | c.2370C>T p.F790= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV101568712; called by muse, varscan2
- KPNA3 | c.1002C>G p.L334= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99904239; called by muse, mutect2, varscan2
- LRRC15 | c.96C>T p.S32= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100752792; called by muse, mutect2, varscan2
- LRRC58 | c.1047G>A p.Q349= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99820225; called by mutect2, varscan2
- MKI67 | c.636G>C p.V212= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100896738; called by muse, mutect2, varscan2
- MSTO1 | c.729G>A p.A243= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs756235713, COSV55471659; called by muse, mutect2, varscan2
- MUC16 | c.9567G>C p.G3189= | Silent (SNP) | VAF 28/190 reads (15%) | catalogued as COSV101200373; called by muse, mutect2
- MXRA5 | c.5820G>C p.V1940= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99477874; called by muse, mutect2, varscan2
- NCOA1 | c.1170C>T p.V390= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV56052477; called by muse, mutect2, varscan2
- NOXO1 | c.111C>T p.F37= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV50191300; called by muse, mutect2, varscan2
- NUP153 | c.4185C>T p.F1395= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV50468016, COSV99467716; called by muse, mutect2, varscan2
- OBSCN | c.771C>G p.L257= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV99481191; called by muse, varscan2
- OPN1MW | c.969C>T p.V323= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as rs1569550455; called by muse, mutect2, varscan2
- PCNX3 | c.3558G>A p.L1186= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100856512; called by muse, mutect2, varscan2
- PDE4DIP | c.858C>G p.L286= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV57732086; called by muse, mutect2, varscan2
- PKD1 | c.3957G>A p.G1319= | Silent (SNP) | VAF 43/240 reads (18%) | catalogued as rs765548935, COSV99238452; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1248C>G p.V416= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100724457; called by muse, mutect2, varscan2
- PODNL1 | c.486G>A p.P162= | Silent (SNP) | VAF 37/296 reads (13%) | catalogued as rs200371573; called by muse, mutect2, varscan2
- POLR2B | c.1876C>T p.L626= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV58898479; called by muse, mutect2, varscan2
- PRG3 | c.79C>T p.L27= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99756005; called by muse, mutect2
- PSMB7 | c.606C>T p.I202= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs549166919, COSV99412976; called by muse, mutect2, varscan2
- RRN3 | c.432C>T p.L144= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV52213858; called by muse, mutect2, varscan2
- RRP12 | c.3108G>C p.R1036= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100213302; called by mutect2, varscan2
- RSPH14 | c.750C>T p.N250= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs567774889, COSV53268927; called by muse, mutect2, varscan2
- RYR2 | c.7425C>A p.V2475= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100771642; called by muse, mutect2, varscan2
- S1PR3 | c.330C>T p.V110= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV100822566; called by muse, mutect2, varscan2
- SCN5A | c.4575G>A p.V1525= (on ENST00000333535 / NM_198056.3; = p.V1524= on NM_000335.5) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100349304; called by muse, mutect2, varscan2
- SLC34A2 | c.1653C>G p.G551= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV101158403; called by muse, mutect2, varscan2
- SOX6 | c.9C>G p.S3= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs1324607185, COSV100322574; called by muse, mutect2, varscan2
- SSTR2 | c.801C>T p.F267= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV100192118; called by muse, mutect2, varscan2
- TBX20 | c.75G>C p.S25= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV101282352; called by muse, mutect2, varscan2
- TG | c.6951C>T p.I2317= | Silent (SNP) | VAF 74/116 reads (64%) | catalogued as rs148528207, COSV55082280; called by muse, mutect2, varscan2
- TMPPE | c.1341C>A p.L447= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100257511; called by muse, mutect2, varscan2
- TTC30B | c.12G>C p.L4= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV101282779; called by muse, mutect2, varscan2
- UBXN11 | c.804C>T p.F268= (on ENST00000374221 / NM_183008.2; = p.F235= on NM_145345.2) | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs1452825926, COSV99582361; called by muse, mutect2, varscan2
- VPS8 | c.4158C>A p.L1386= (on ENST00000625842 / NM_001349294.1; = p.L1384= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV99802831; called by muse, mutect2, varscan2
- WDR92 | c.1038G>C p.V346= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99718383; called by muse, mutect2
- ZER1 | c.2091C>T p.V697= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV99402203; called by muse, mutect2, varscan2
- ZNF142 | c.3045A>C p.A1015= (on ENST00000411696 / NM_001379660.1; = p.A815= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs1056875195, COSV101376955; called by muse, mutect2
- ZNF20 | c.456C>T p.F152= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100503089; called by muse, mutect2, varscan2
- ZNF467 | c.591C>T p.F197= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs1461277407, COSV100118014; called by muse, mutect2
- AL353804.4 | chrX:73823064 T>A | 5'Flank (SNP) | VAF 15/117 reads (13%) | called by muse, mutect2, varscan2
- MIR129-2 | n.7T>C | RNA (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- MIR129-2 | n.8C>T | RNA (SNP) | VAF 13/69 reads (19%) | catalogued as rs1218456690; called by muse, mutect2, varscan2
- MIR1302-3 | n.23T>G | RNA (SNP) | VAF 39/416 reads (9%) | called by muse, mutect2
- MLF1 | c.195+806G>A | Intron (SNP) | VAF 23/84 reads (27%) | catalogued as rs779983108, COSV100576026; called by muse, mutect2, varscan2
- TADA1 | c.-2C>T | 5'UTR (SNP) | VAF 13/87 reads (15%) | catalogued as rs200126309, COSV100902345; called by muse, mutect2, varscan2
